Somatic mutation profile of tumor specimen C3L-00938-01 (aliquot CPT0016260006) from CPTAC case C3L-00938, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 53.1 years (19,395 days).
Specimen C3L-00938-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2987d681-d8bb-4df5-8639-741ae65d9bb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00938-71 (Blood Derived Normal), aliquot CPT0016330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c135d538-eb3d-41f4-994d-a47b82c1aaac

The open-access MAF lists 53 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 12, Intron 4, Frame Shift Del 3, RNA 2, Nonsense Mutation 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 27/304 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PTEN | c.276C>G p.D92E | Missense Mutation (SNP) | VAF 28/361 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM033666, COSV64288954, COSV64292660; called by muse, mutect2
- ADAD1 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56641370; called by muse, mutect2
- DGAT1 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1315358048, COSV100183925; called by muse, mutect2
- DOCK8 | c.5381A>G p.Y1794C | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66619356; called by muse, mutect2
- FBXL8 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 15/239 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs756116891; called by muse, mutect2
- MSL2 | c.75del p.K26Rfs*50 | Frame Shift Del (DEL) | VAF 15/167 reads (9%) | catalogued as COSV59444326; called by mutect2, pindel
- NBPF10 | c.10742G>A p.C3581Y | Missense Mutation (SNP) | VAF 21/858 reads (2%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.879); catalogued as rs782149601; called by muse, mutect2
- ZNF185 | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 12/226 reads (5%) | catalogued as rs782238766, COSV100248746; called by muse, mutect2
- A1BG | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 19/363 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADGRL3 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2
- ALPK3 | c.2641G>A p.A881T | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- AMN | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 16/480 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.907); called by muse, mutect2
- ANKRD44 | c.464T>C p.M155T | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); called by muse, mutect2
- ARID5B | c.1351del p.S451Afs*28 | Frame Shift Del (DEL) | VAF 14/162 reads (9%) | called by mutect2, pindel
- ASH1L | c.6166A>G p.I2056V (on ENST00000368346 / NM_001366177.2; = p.I2051V on NM_018489.3) | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); called by muse, mutect2
- BIVM-ERCC5 | c.2491G>A p.A831T | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); called by muse, mutect2
- CARD6 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- CARMIL3 | c.2260T>C p.S754P | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- CDK5RAP2 | c.3613C>T p.Q1205* | Nonsense Mutation (SNP) | VAF 10/277 reads (4%) | called by muse, mutect2
- CENPB | c.1721T>C p.L574S | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CLOCK | c.1388C>A p.P463H | Missense Mutation (SNP) | VAF 12/283 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2
- CRYBB2 | c.547del p.Q183Rfs*50 | Frame Shift Del (DEL) | VAF 14/182 reads (8%) | called by mutect2, pindel
- DYNC2H1 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- IGF2BP3 | c.1615A>G p.I539V | Missense Mutation (SNP) | VAF 9/203 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2
- MYO1C | c.2212+1G>C p.X738_splice (on ENST00000648651 / NM_001080779.2; = p.X703_splice on NM_033375.5) | Splice Site (SNP) | VAF 18/358 reads (5%) | called by muse, mutect2
- PCDH17 | c.1826C>T p.T609I | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.241); called by muse, mutect2
- PRSS58 | c.481T>C p.S161P | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2
- RPRD1B | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- RPTN | c.563A>G p.Q188R | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2
- SEZ6L | c.1790G>A p.G597D | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMG1 | c.8666G>A p.G2889D | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- TMC7 | c.1613T>A p.F538Y | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZBTB45 | c.700C>A p.P234T | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.231); called by muse, mutect2
- CACNA1S | c.4641G>A p.R1547= | Silent (SNP) | VAF 18/422 reads (4%) | called by muse, mutect2
- CCIN | c.375T>C p.I125= | Silent (SNP) | VAF 12/324 reads (4%) | called by muse, mutect2
- EXPH5 | c.1818A>G p.V606= | Silent (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- FBXL18 | c.162T>C p.R54= | Silent (SNP) | VAF 15/263 reads (6%) | called by muse, mutect2
- IQCF1 | c.513C>A p.G171= | Silent (SNP) | VAF 14/338 reads (4%) | called by muse, mutect2
- MARK4 | c.1701C>T p.S567= | Silent (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- MOGS | c.1863T>C p.A621= | Silent (SNP) | VAF 8/157 reads (5%) | called by muse, mutect2
- MYRIP | c.1140G>A p.L380= | Silent (SNP) | VAF 11/244 reads (5%) | called by muse, mutect2
- PEX6 | c.630C>T p.S210= | Silent (SNP) | VAF 12/390 reads (3%) | called by muse, mutect2
- SNAPC4 | c.676C>T p.L226= | Silent (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- TSPO2 | c.498G>T p.T166= | Silent (SNP) | VAF 17/319 reads (5%) | called by muse, mutect2
- ZBTB44 | c.1641C>T p.H547= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as rs567827421, COSV63537219; called by muse, mutect2
- ANKRD13D | c.*1194G>A | 3'UTR (SNP) | VAF 7/175 reads (4%) | catalogued as COSV100354447, COSV57383905; called by muse, mutect2
- EGFR | c.1881-665C>T | Intron (SNP) | VAF 12/291 reads (4%) | called by muse, mutect2
- GABRB3 | c.461+5316A>T | Intron (SNP) | VAF 7/129 reads (5%) | catalogued as rs1474420355; called by muse, mutect2
- HAS2-AS1 | n.780C>T | RNA (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- LINC02453 | n.149G>T | RNA (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- RPL37A | c.133-62C>A | Intron (SNP) | VAF 10/230 reads (4%) | called by muse, mutect2
- THAP1 | c.71+15C>T | Intron (SNP) | VAF 11/258 reads (4%) | called by muse, mutect2
